CCDI case PBCGCC — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Spinal cord, cranial nerves, and other parts of central nervous system.
https://portal.gdc.cancer.gov/cases/75fcce7c-da45-4f50-a395-4b2c9bb46b01

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Neoplasm, uncertain whether benign or malignant: ICD-O-3 morphology code: 8000/1; Tissue or organ of origin: Spinal cord; Age at diagnosis: 12.8 years (4,685 days).

Biospecimens (2 samples)
- Sample 0DRB5M: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DRB5X: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
